Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5494, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5494-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED]

[REDACTED] the patient also has a history of biopsy on [REDACTED] his biopsy reveals bilateral poorly differentiated prostatic adenocarcinoma.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical retropubic prostatectomy.

TCGA - EJ - 5494

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NINE LYMPH NODES, NO TUMOR SEEN (0/9).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
EIGHT LYMPH NODES, NO TUMOR SEEN (0/8).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 4+3=7.
- B. CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT SIDES OF PROSTATE AND HAS A GREATEST NODULAR DIAMETER OF 2.3 CM IN ONE HISTOLOGIC SECTION.
- C. THE TUMOR INVOLVES APPROXIMATELY 60% OF THE EXAMINED PROSTATE VOLUME.
- D. EXTRA-PROSTATIC EXTENSION IS PRESENT AT THE RIGHT ANTERIOR ASPECT AND LEFT ANTERIOR ASPECT OF THE GLAND (BLOCKS 3L, 3M, 3N, 3U, 3PP, 3TT, 3VV).
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. THE SURGICAL RESECTION MARGIN IS FREE OF TUMOR; TUMOR EXTENDS TO WITHIN 0.1 mm OF THE RESECTION MARGIN AT THE ANTERIOR RIGHT APEX (BLOCK 3K).
- G. EXTENSIVE PERINEURAL INVASION IS PRESENT.
- H. ANGIOLYMPHATIC INVASION IS NOT IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS PRESENT.
- J. PATHOLOGIC TNM STAGE: pT3a N0 MX
- K. BACKGROUND PROSTATIC TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 3.75
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	70%
WEIGHT OF PROSTATE:	62.18gm
TUMOR SIZE:	Maximum dimension: 2.3 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Multifocal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	17
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file ccafc782-b84a-41e2-86b4-554ee8642316 (TCGA-EJ-5494.E52EEFBC-E27D-4A5D-A261-D06A2DCF5D53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).